Somatic mutation profile of tumor specimen TCGA-V4-A9EA-01A (aliquot TCGA-V4-A9EA-01A-11D-A39W-08) from TCGA case TCGA-V4-A9EA, project TCGA-UVM (Uveal Melanoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Spindle cell melanoma, NOS; Tissue or organ of origin: Choroid; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 66.3 years (24,234 days).
Specimen TCGA-V4-A9EA-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4a6d5bf7-273c-4397-80aa-6fa677c836b7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-V4-A9EA-10A (Blood Derived Normal), aliquot TCGA-V4-A9EA-10A-01D-A39Z-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7115e4c3-3171-4fbd-9054-1636eddc8602

The open-access MAF lists 10 somatic variants for this specimen: 8 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 8, Silent 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GNAQ | c.626A>T p.Q209L | Missense Mutation (SNP) | VAF 42/86 reads (49%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913492, COSV54105903, COSV54105914, COSV54108414; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- SF3B1 | c.1873C>T p.R625C | Missense Mutation (SNP) | VAF 28/67 reads (42%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs775623976, COSV59205859, COSV59212489, COSV59228873; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- C6orf89 | c.614C>T p.A205V (on ENST00000373685; = p.A212V on NM_152734.4) | Missense Mutation (SNP) | VAF 135/220 reads (61%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs753250574, COSV62101231; called by muse, mutect2, varscan2
- CRISPLD2 | c.1472G>A p.R491Q | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.632); catalogued as rs147087796; called by muse, mutect2, varscan2
- DSCAML1 | c.4780G>A p.G1594R (on ENST00000321322; = p.G1534R on NM_020693.4) | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT tolerated (0.46); PolyPhen benign (0.375); catalogued as rs527533395; called by muse, mutect2, varscan2
- TBX6 | c.293G>A p.R98Q | Missense Mutation (SNP) | VAF 25/44 reads (57%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs767360040; called by muse, mutect2, varscan2
- MORC2 | c.1662G>A p.M554I (on ENST00000397641 / NM_001303256.3; = p.M492I on NM_014941.3) | Missense Mutation (SNP) | VAF 63/129 reads (49%) | SIFT tolerated (0.22); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZSWIM1 | c.100A>G p.M34V | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT tolerated (0.5); PolyPhen benign (0); called by mutect2, varscan2
- ACVRL1 | c.933G>A p.A311= | Silent (SNP) | VAF 14/36 reads (39%) | catalogued as rs779758131; called by muse, mutect2, varscan2
- ITPR3 | c.6015G>A p.E2005= | Silent (SNP) | VAF 64/97 reads (66%) | called by muse, mutect2, varscan2
